Gene-level copy-number profile of tumor specimen TCGA-97-7553-01A from TCGA case TCGA-97-7553, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.9 years (21,518 days).
Specimen TCGA-97-7553-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.15755421-0d2e-41e4-b766-3d1eac5ce537.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-97-7553-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6a48473-aacb-4723-9ab3-4a730d17e72d

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 31,632; copy number 2: 23,116; copy number 3: 3,117; copy number 4: 1,753; copy number 5: 39; copy number 6: 120; copy number 8: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-97-7553-01A-21D-2035-01): tumor purity 0.29, ploidy 1.44, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:89,737,549–90,222,851, 23 genes: FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,043 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 4–6 (broad region; genes not listed).
- chr6:167,607–58,438,364, 1,527 genes, copy number 3–5 (broad region; genes not listed).
- chr7:70,972–38,335,514, 683 genes, copy number 3–8 (broad region; genes not listed).
- chr8:150,584–1,963,131, 40 genes, copy number 4 (within-gene range 2–4): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9.
- chr8:8,895,813–9,906,678, 26 genes, copy number 4: RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1.
- chr8:12,467,693–12,665,588, 1 gene, copy number 3 (within-gene range 2–3): AC068587.4.
- chr8:12,570,350–15,766,649, 47 genes, copy number 3: RPS3AP34, AC068587.2, AC068587.8, AC068587.6, RPS3AP35, AC068587.3, AC068587.7, AC068587.5, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1, AC103851.1, TUSC3, AC100850.1.
- chr8:17,224,966–19,758,029, 51 genes, copy number 4 (within-gene range 2–4): CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2, PCM1, ASAH1, AC124242.1, AC124242.2, AC124242.3, NAT1, MTND4LP26, NATP, AC025062.1, AC025062.3, AC025062.2, NAT2, PSD3, AC100800.1, RPL35P6, AC087821.2, AC087821.1, SNORA62, AC009884.1, AC009884.2, AC100849.1, AC100849.2, AC068880.1, AC068880.3, AC068880.2, AC068880.5, SH2D4A, AC068880.4, CSGALNACT1, AC090541.1.
- chr8:20,551,201–129,844,504, 1,709 genes, copy number 3–4 (broad region; genes not listed).
- chr8:129,864,478–129,868,716, 2 genes, copy number 3: AC022973.2, AC022973.1.
- chr8:139,727,725–142,209,003, 42 genes, copy number 3 (within-gene range 1–3): TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1, AC025839.1, MIR1302-7, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051.
- chr8:142,247,585–142,247,866, 1 gene, copy number 3: RN7SL260P.
- chr14:22,132,553–22,505,167, 57 genes, copy number 4: TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36.
- chr15:31,475,398–39,427,195, 147 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29,211. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
